Gene-level copy-number profile of tumor specimen TCGA-AG-A01W-01A from TCGA case TCGA-AG-A01W, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage II; Age at diagnosis: 67.7 years (24,745 days).
Specimen TCGA-AG-A01W-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-READ.9046317c-b457-4702-9c00-536c520f1cef.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AG-A01W-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/057e4dc9-66f3-4b15-b8d7-b5373ad54e68

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 23; copy number 1: 924; copy number 2: 13,679; copy number 3: 30,857; copy number 4: 12,833; copy number 5: 1,499.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AG-A01W-01A-21D-A080-01): tumor purity 0.61, ploidy 2.99, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 23 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:188,400,736–189,291,336, 12 genes (within-gene range 0–2): LINC01060, AC093909.3, AC093909.5, RNU7-192P, AC093909.1, AC093909.6, AC093909.2, LINC02508, AC093909.4, AC122138.1, AC107391.1, AC105924.1.
- chr15:66,931,537–67,195,169, 5 genes (within-gene range 0–3): LINC02206, AC087482.1, HMGN2P47, SMAD3, AC012568.1.
- chr18:47,285,725–47,703,745, 6 genes (within-gene range 0–1): MIR4527HG, MIR4527, AC102797.2, AC102797.1, TPMTP1, AC026898.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 924. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
